Somatic mutation profile of tumor specimen C3L-01463-01 (aliquot CPT0389910006) from CPTAC case C3L-01463, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 54.3 years (19,822 days).
Specimen C3L-01463-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da62e9f9-d752-4f24-bb0f-58d27f6d018c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01463-31 (Blood Derived Normal), aliquot CPT0389940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/037dc2bf-c2cd-4eb4-be86-442700bd9691

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Splice Site 2, In Frame Del 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8orf34 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated, low confidence (0.24); called by muse, mutect2, varscan2
- DNAH9 | c.11162A>C p.E3721A | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DNAJC13 | c.755_760del p.K252_V254delinsI | In Frame Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- DPF3 | c.641G>A p.S214N | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- FLCN | c.324C>A p.S108R | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0753 | c.2351_2358+1del p.X784_splice | Splice Site (DEL) | VAF 12/64 reads (19%) | called by mutect2, varscan2
- MAP7 | c.2239+1G>T p.X747_splice | Splice Site (SNP) | VAF 55/321 reads (17%) | called by muse, mutect2, varscan2
- RBM20 | c.223_224del p.S75Gfs*3 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by pindel, varscan2
- RFNG | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SOBP | c.1912G>A p.G638S | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF273 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AHNAK | c.13620C>T p.S4540= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV57209581; called by muse, mutect2, varscan2
- COBLL1 | c.3510T>C p.A1170= (on ENST00000392717; = p.A1132= on NM_014900.5) | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2
- DISP2 | c.2100C>T p.I700= | Silent (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- GLI2 | c.4371A>G p.P1457= (on ENST00000361492 / NM_001374353.1; = p.P1474= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/212 reads (20%) | catalogued as rs935240615; called by muse, mutect2, varscan2
- TRIM2 | c.1818G>T p.G606= (on ENST00000437508; = p.G633= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 50/260 reads (19%) | called by muse, mutect2, varscan2
- DOT1L | c.2806+43_2806+44del | Intron (DEL) | VAF 54/267 reads (20%) | called by mutect2, pindel, varscan2
